Somatic mutation profile of tumor specimen 0DR6Y8 from CCDI case PBCEPN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 12.5 years (4,578 days).
Specimen 0DR6Y8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c4f0b2-00ae-4403-b8c0-6cdf8cce8cc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6XY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81e25bb4-15ef-46c2-8f7c-515184ba5d9a

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Silent 3, Missense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 66/1274 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.118); catalogued as rs189716582, COSV100729697; called by muse, mutect2
- COL12A1 | c.6210+1G>A p.X2070_splice | Splice Site (SNP) | VAF 54/1336 reads (4%) | called by muse, mutect2
- DHX8 | c.2344G>A p.G782S | Missense Mutation (SNP) | VAF 34/1186 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS41 | c.1022_1025del p.E341Gfs*8 | Frame Shift Del (DEL) | VAF 120/1206 reads (10%) | called by mutect2, pindel
- ABTB2 | c.2952G>A p.E984= | Silent (SNP) | VAF 49/925 reads (5%) | called by muse, mutect2
- MLYCD | c.1401C>A p.S467= | Silent (SNP) | VAF 99/893 reads (11%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 61/1659 reads (4%) | called by muse, mutect2
- ARL8B | c.204+71C>A | Intron (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- PADI4 | c.1155+24G>A | Intron (SNP) | VAF 46/381 reads (12%) | called by muse, mutect2, varscan2
- SORD | c.908+73G>A | Intron (SNP) | VAF 14/117 reads (12%) | called by mutect2, varscan2
